Somatic mutation profile of tumor specimen dffcac99-9eac-4717-aeb6-f4a2e7 (aliquot dffcac99-9eac-4717-aeb6-f4a2e7_D6) from CPTAC case 09CO013, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen dffcac99-9eac-4717-aeb6-f4a2e7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c07e1e56-44f6-44e5-b0c3-b7b244df41f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 71972f70-36ac-4508-adc4-766715 (Blood Derived Normal), aliquot 71972f70-36ac-4508-adc4-766715_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6073018c-7c70-4645-8c8f-14ccac6c6144

The open-access MAF lists 190 somatic variants for this specimen: 129 protein-altering or splice-affecting, 42 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 42, Nonsense Mutation 11, Intron 9, 5'UTR 3, Frame Shift Ins 3, Splice Site 3, Frame Shift Del 2, 3'Flank 2, Splice Region 2, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 62/122 reads (51%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CHD4 | c.3164G>A p.R1055H (on ENST00000357008 / NM_001363606.2; = p.R1068H on NM_001273.5) | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs886039915, COSV58894318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs112911555, CM091207; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 125/299 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGRN | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs149868381; called by muse, mutect2, varscan2
- ALDH4A1 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1393290767; called by muse, mutect2
- ANKRD24 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as rs1245933813; called by muse, mutect2, varscan2
- ARNTL | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1218467493; called by muse, mutect2, varscan2
- BIK | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1178343321; called by muse, varscan2
- C2CD6 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs756027630, COSV53793307; called by muse, mutect2, varscan2
- CACNA1A | c.6698G>A p.R2233H | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1064793075, COSV64201150; called by mutect2, varscan2
- CAPN5 | c.854C>T p.A285V (on ENST00000456580; = p.A245V on NM_004055.5) | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1555041542; called by muse, mutect2, varscan2
- CAPRIN2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs767441129; called by muse, mutect2, varscan2
- CCDC57 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 67/160 reads (42%) | catalogued as rs777714729; called by muse, mutect2, varscan2
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2, varscan2
- CDHR2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.273); catalogued as rs764089283, COSV56145191; called by muse, mutect2, varscan2
- CDIN1 | c.*37-1G>A | Splice Site (SNP) | VAF 14/101 reads (14%) | catalogued as rs766873092; called by muse, mutect2, varscan2
- CFAP57 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368874977; called by muse, mutect2, varscan2
- CNTNAP2 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs369724886, COSV62260830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 152/421 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752639793; called by mutect2, varscan2
- CSMD2 | c.7961G>A p.R2654Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1000408473, COSV53942325, COSV53971497; called by muse, mutect2, varscan2
- DCHS1 | c.7600G>T p.E2534* | Nonsense Mutation (SNP) | VAF 237/610 reads (39%) | catalogued as COSV54999239; called by muse, mutect2, varscan2
- F13A1 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs370205818; called by muse, mutect2, varscan2
- FAM83F | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 62/404 reads (15%) | catalogued as rs761928217; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 62/190 reads (33%) | catalogued as rs754199513; called by mutect2, varscan2
- GTPBP1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1370141812; called by mutect2, varscan2
- IGF2R | c.2107G>A p.G703R | Missense Mutation (SNP) | VAF 93/167 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100806875; called by mutect2, varscan2
- IGHV3-66 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 99/496 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.141); catalogued as rs782513119; called by muse, mutect2
- IL9R | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs1186714865, COSV99054946; called by muse, varscan2
- KAT6A | c.1126T>G p.S376A | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.097); catalogued as rs372220602; called by muse, mutect2, varscan2
- KDM4B | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.062); catalogued as rs756458000; called by muse, mutect2, varscan2
- LILRB1 | c.974G>A p.R325H (on ENST00000427581; = p.R289H on NM_006669.6) | Missense Mutation (SNP) | VAF 92/587 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs553317698, COSV61116803, COSV61120756; called by muse, mutect2, varscan2
- LMNB1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs533097546; called by muse, mutect2, varscan2
- MAGEC3 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 91/114 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV71610047; called by muse, mutect2, varscan2
- MAGI2 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV100836995; called by muse, mutect2, varscan2
- MAST2 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs778296919, COSV100789052; called by muse, mutect2, varscan2
- MDN1 | c.10715G>A p.R3572Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs372206396; called by muse, mutect2, varscan2
- MOS | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV61335946; called by muse, mutect2, varscan2
- NAAA | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs751516956; called by muse, mutect2, varscan2
- NEB | c.3160G>T p.A1054S | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.995); catalogued as COSV51455330; called by muse, mutect2, varscan2
- NEK5 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1317458339; called by muse, mutect2
- NIPBL | c.3403C>T p.H1135Y | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV56961317, COSV99238667; called by muse, mutect2, varscan2
- NLRP8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs764375811, COSV52585164; called by muse, mutect2, varscan2
- NLRP9 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs149638733; called by muse, mutect2, varscan2
- NMRK2 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as rs775886226, COSV51455448; called by muse, mutect2, varscan2
- NRP2 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753855535, COSV99785795; called by muse, mutect2, varscan2
- OR2J2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs371365216; called by muse, mutect2, varscan2
- OR5D14 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV59459079; called by muse, mutect2, varscan2
- OR6M1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142281019, COSV100484057; called by muse, mutect2, varscan2
- OTOP3 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 214/432 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs569900376, COSV60913929; called by muse, mutect2, varscan2
- PCDHA12 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 170/393 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV56496461; called by muse, mutect2, varscan2
- PCDHGB6 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 178/432 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1000014772, COSV53909164; called by mutect2, varscan2
- PIPOX | c.24G>C p.W8C | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746060207; called by muse, mutect2
- PKHD1L1 | c.3064G>A p.G1022S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV65736179; called by muse, mutect2, varscan2
- PRRC2A | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs145145943; called by muse, mutect2, varscan2
- PSG9 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs374762718, COSV52486368, COSV52488592; called by muse, mutect2, varscan2
- PTPRN | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757908552, COSV55345360; called by muse, mutect2, varscan2
- PTX4 | c.883C>T p.R295* (on ENST00000447419 / NM_001328608.2; = p.R290* on NM_001013658.1) | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs757126891, COSV53518953; called by muse, mutect2
- RELN | c.5689G>T p.E1897* | Nonsense Mutation (SNP) | VAF 265/601 reads (44%) | catalogued as COSV59034634; called by muse, mutect2, varscan2
- RPUSD2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV59765548; called by muse, mutect2, varscan2
- SAMD9 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 16/304 reads (5%) | catalogued as COSV101180329; called by muse, mutect2
- SIPA1L2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53399072; called by muse, mutect2, varscan2
- SLC12A2 | c.2475+2T>C p.X825_splice | Splice Site (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99320908; called by mutect2, varscan2
- SLC1A4 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV52234987; called by muse, mutect2, varscan2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 52/500 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2, varscan2
- SLC27A3 | c.821C>T p.A274V (on ENST00000271857; = p.A146V on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs755936017; called by muse, mutect2, varscan2
- SLC34A2 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as COSV65942114; called by muse, mutect2, varscan2
- SLC35G5 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 258/845 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99644272; called by muse, mutect2, varscan2
- SLC8A3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs982655652, COSV63521042, COSV63523482; called by muse, mutect2, varscan2
- SLCO1B1 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1456418208, COSV57007321; called by muse, mutect2, varscan2
- SNX14 | c.2521G>A p.E841K (on ENST00000314673 / NM_001350535.1; = p.E788K on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59009644; called by muse, mutect2, varscan2
- SNX3 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV100018017; called by muse, mutect2, varscan2
- SPG11 | c.4743G>A p.T1581= | Splice Region (SNP) | VAF 34/217 reads (16%) | catalogued as rs762755586; called by muse, mutect2, varscan2
- STBD1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99421609; called by muse, mutect2, varscan2
- TAMALIN | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 201/439 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201892327; called by muse, mutect2, varscan2
- TMCC2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1467212790; called by muse, mutect2, varscan2
- TRPV6 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.636); catalogued as rs773785976, COSV63891095; called by muse, mutect2, varscan2
- TSC22D4 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs756042817; called by muse, mutect2, varscan2
- TTC21A | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 164/630 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764381681, COSV56188716; called by muse, mutect2, varscan2
- TUBGCP6 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 112/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282749907; called by muse, mutect2, varscan2
- URGCP | c.1319G>A p.R440Q (on ENST00000453200 / NM_001077663.3; = p.R431Q on NM_017920.4) | Missense Mutation (SNP) | VAF 121/536 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.645); catalogued as rs201905853, COSV99787501; called by muse, mutect2, varscan2
- ZNF225 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs762062304, COSV53472108; called by muse, mutect2, varscan2
- ZNF665 | c.939G>T p.E313D (on ENST00000600412; = p.E378D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs746996904; called by muse, mutect2, varscan2
- ANK2 | c.3745A>G p.N1249D | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- CCDC168 | c.9037C>A p.Q3013K | Missense Mutation (SNP) | VAF 138/314 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.148); called by muse, mutect2
- CCM2 | c.915+5del | Splice Region (DEL) | VAF 83/306 reads (27%) | called by mutect2, pindel, varscan2
- CHD5 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CNTNAP4 | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL11A2 | c.1358C>A p.P453Q (on ENST00000341947 / NM_080680.3; = p.P346Q on NM_080679.2) | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.5801C>A p.P1934H | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM155B | c.192C>A p.C64* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FAT2 | c.6688C>A p.P2230T | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FBXO30 | c.1664G>A p.C555Y | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FN1 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 49/391 reads (13%) | called by muse, mutect2, varscan2
- H2AC8 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IGDCC4 | c.2687G>A p.W896* | Nonsense Mutation (SNP) | VAF 112/203 reads (55%) | called by muse, mutect2, varscan2
- IRX5 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- JAKMIP1 | c.2462del p.L821Cfs*5 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- JMJD6 | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KLF2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- KLF2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- LHX6 | c.797G>A p.W266* (on ENST00000373755 / NM_001242334.2; = p.W295* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 152/380 reads (40%) | called by muse, mutect2, varscan2
- MMP7 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NASP | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NFKBIA | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 54/457 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- OR5V1 | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PANX2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PIK3CB | c.356_373del p.G119_K125delinsE | In Frame Del (DEL) | VAF 68/143 reads (48%) | called by mutect2, pindel, varscan2
- POGLUT3 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RPL23A | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 113/197 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SLC12A4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPIN2B | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 73/98 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- SUPT5H | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TFPT | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- TLCD3B | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 153/423 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TMEM209 | c.425A>T p.Y142F | Missense Mutation (SNP) | VAF 161/243 reads (66%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRPM5 | c.3070C>T p.L1024F | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- UHMK1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- USF2 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- VAX1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VSIG10 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- VWF | c.7433G>T p.R2478L | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WWC1 | c.2659-1G>A p.X887_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- ZBTB44 | c.426_427dup p.A143Vfs*29 | Frame Shift Ins (INS) | VAF 43/304 reads (14%) | called by mutect2, varscan2
- ZC3HC1 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZDHHC13 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF281 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, varscan2
- ZNF804B | c.2040C>A p.N680K | Missense Mutation (SNP) | VAF 51/440 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ASXL3 | c.2361C>T p.S787= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs374512885, COSV99325633; called by muse, mutect2, varscan2
- ATP1A2 | c.153C>T p.R51= | Silent (SNP) | VAF 77/346 reads (22%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.2259C>T p.H753= | Silent (SNP) | VAF 114/469 reads (24%) | catalogued as rs939380273; called by muse, mutect2, varscan2
- BLVRA | c.339G>A p.L113= | Silent (SNP) | VAF 113/378 reads (30%) | called by muse, mutect2, varscan2
- C9orf50 | c.1257C>T p.L419= | Silent (SNP) | VAF 97/254 reads (38%) | catalogued as rs1047724161; called by muse, mutect2, varscan2
- CCDC116 | c.1470C>T p.S490= | Silent (SNP) | VAF 155/405 reads (38%) | called by muse, mutect2, varscan2
- CLTC | c.1890C>T p.F630= | Silent (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- CRHBP | c.741G>T p.L247= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- CRNKL1 | c.1743G>A p.Q581= | Silent (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- DCP1A | c.294A>G p.R98= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- DMD | c.9525G>A p.V3175= | Silent (SNP) | VAF 283/348 reads (81%) | catalogued as rs1060502622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPEP2 | c.195T>C p.S65= | Silent (SNP) | VAF 31/280 reads (11%) | called by muse, mutect2, varscan2
- FAT4 | c.1365C>T p.R455= | Silent (SNP) | VAF 96/410 reads (23%) | called by muse, mutect2
- FBN3 | c.4341C>T p.N1447= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs767187366; called by muse, mutect2, varscan2
- GATD3A | c.732C>T p.C244= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs372249793; called by mutect2, varscan2
- GOLM2 | c.117C>T p.H39= | Silent (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- GPR37 | c.24C>T p.L8= | Silent (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- GPR85 | c.477C>T p.D159= | Silent (SNP) | VAF 162/340 reads (48%) | catalogued as rs376463244; called by muse, mutect2, varscan2
- IZUMO1 | c.618G>A p.T206= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as rs751561047, COSV55805460; called by muse, mutect2, varscan2
- KNDC1 | c.153C>T p.S51= | Silent (SNP) | VAF 134/351 reads (38%) | catalogued as rs776048059; called by muse, mutect2, varscan2
- MCFD2 | c.195G>A p.A65= | Silent (SNP) | VAF 119/630 reads (19%) | catalogued as rs752268860, COSV60178217; called by muse, mutect2, varscan2
- MFRP | c.168G>A p.G56= (on ENST00000449574; = p.G432= on NM_031433.4) | Silent (SNP) | VAF 173/469 reads (37%) | called by muse, mutect2, varscan2
- MMP17 | c.561C>T p.I187= | Silent (SNP) | VAF 168/461 reads (36%) | catalogued as rs1197252162, COSV100861890; called by muse, mutect2, varscan2
- MON1B | c.1605G>A p.T535= | Silent (SNP) | VAF 119/316 reads (38%) | catalogued as rs1174188848; called by muse, mutect2, varscan2
- NR3C2 | c.609G>A p.S203= | Silent (SNP) | VAF 81/339 reads (24%) | catalogued as COSV60997795; called by muse, mutect2, varscan2
- NTNG1 | c.1134G>A p.L378= | Silent (SNP) | VAF 80/196 reads (41%) | called by muse, varscan2
- OR10R2 | c.183C>A p.G61= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs375553926; called by muse, mutect2, varscan2
- PCDH9 | c.1197G>T p.V399= | Silent (SNP) | VAF 79/278 reads (28%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.2334G>A p.T778= | Silent (SNP) | VAF 85/327 reads (26%) | catalogued as rs750081761, COSV53893465; called by muse, mutect2, varscan2
- PIK3R2 | c.30C>T p.R10= | Silent (SNP) | VAF 59/209 reads (28%) | catalogued as rs1213935106; called by muse, mutect2, varscan2
- PNPLA7 | c.3027C>T p.S1009= | Silent (SNP) | VAF 150/407 reads (37%) | catalogued as rs746093536; called by muse, mutect2, varscan2
- SAGE1 | c.1369T>C p.L457= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- SEC24D | c.2877G>T p.L959= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- SLC16A8 | c.1233C>T p.I411= | Silent (SNP) | VAF 110/318 reads (35%) | called by muse, mutect2, varscan2
- TMEM160 | c.543G>A p.E181= | Silent (SNP) | VAF 69/181 reads (38%) | called by muse, mutect2, varscan2
- TMEM63C | c.1902G>A p.T634= | Silent (SNP) | VAF 85/226 reads (38%) | catalogued as rs201898601, COSV53609128; called by muse, mutect2, varscan2
- TOGARAM2 | c.1920C>T p.G640= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs572087189; called by muse, mutect2, varscan2
- TRAPPC12 | c.435G>A p.A145= | Silent (SNP) | VAF 85/138 reads (62%) | called by muse, mutect2, varscan2
- TTF1 | c.249C>T p.L83= | Silent (SNP) | VAF 93/207 reads (45%) | called by muse, mutect2, varscan2
- UHMK1 | c.240G>A p.L80= | Silent (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- USP54 | c.2742T>C p.D914= | Silent (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- XG | c.468G>A p.L156= | Silent (SNP) | VAF 54/64 reads (84%) | called by muse, varscan2
- AGBL4 | c.34+28418C>T | Intron (SNP) | VAF 25/142 reads (18%) | catalogued as rs577725452; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840090 G>A | 5'Flank (SNP) | VAF 155/373 reads (42%) | catalogued as rs1347160859, COSV100004890; called by muse, mutect2, varscan2
- ANKRD26P1 | chr16:46517989 C>T | 5'Flank (SNP) | VAF 39/114 reads (34%) | catalogued as rs1427768471; called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405454 C>T | 3'Flank (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- ENPP2 | c.973-2111C>T | Intron (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- ERLIN2 | c.425-1724C>T | Intron (SNP) | VAF 142/483 reads (29%) | catalogued as rs1467078718; called by muse, mutect2, varscan2
- ETV5 | c.-67C>T | 5'UTR (SNP) | VAF 65/100 reads (65%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+590G>T | Intron (SNP) | VAF 79/182 reads (43%) | called by muse, mutect2, varscan2
- MEFV | c.1610+31G>A | Intron (SNP) | VAF 65/184 reads (35%) | called by muse, mutect2, varscan2
- MEIS3 | c.*73T>A | 3'UTR (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- MIR205 | chr1:209432281 G>A | 3'Flank (SNP) | VAF 48/250 reads (19%) | catalogued as rs760896460; called by muse, mutect2, varscan2
- MIR7-3 | n.67G>A | RNA (SNP) | VAF 88/194 reads (45%) | catalogued as rs1449416902; called by muse, mutect2, varscan2
- NDUFA11 | c.-27C>T | 5'UTR (SNP) | VAF 104/353 reads (29%) | catalogued as rs985887880; called by muse, mutect2, varscan2
- NELL1 | c.1549+54832G>T | Intron (SNP) | VAF 102/304 reads (34%) | catalogued as COSV54258369; called by muse, mutect2, varscan2
- PRR5 | c.323-23G>A | Intron (SNP) | VAF 95/271 reads (35%) | called by muse, mutect2, varscan2
- ROBO2 | c.3935-1784C>A | Intron (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5084+75C>T | Intron (SNP) | VAF 31/205 reads (15%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.575C>T | RNA (SNP) | VAF 35/95 reads (37%) | catalogued as rs764190440; called by muse, mutect2, varscan2
- UBQLN2 | c.-34G>A | 5'UTR (SNP) | VAF 13/15 reads (87%) | catalogued as rs1298044294; called by muse, mutect2, varscan2
